Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0WX, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0WX-01A (Primary Tumor).

[page 1 of 2]
1/25/11 *hw*

Surgical Pathology

Criteria		
HVA/A Discrepancy		
Dual/Synchronous Primary History	QUALIFIED	DISQUALIFIED
Case's circle:		

[page 2 of 2]
c-erbB-2 oncoprotein which is an affinity-isolated antibody product number). The immunostaining is performed after antigen retrieval by heating the unstained sections at 95 degrees centigrade for 20 minutes in 10 mM citrate buffer, pH 6.0. The primary antibody is used at a dilution of 1:3000 (manual staining), with an incubation for one hour at 37 degrees centigrade. The Histostain Plus kit () is used as the detection system. Rare tumor cells exhibit barely perceptible, complete membrane staining, but their number is too few to indicate overexpression of HER2/neu oncoprotein. The majority of tumor tumor cells have barely perceptible, focal membrane staining (score = 1+), indicating that the tumor does NOT overexpress HER2/neu oncoprotein.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

, M.D., Ph.D. Pager :

Electronically signed:

Source: NCI Genomic Data Commons file cae872cd-a78b-4b70-84e5-2f3bf9b312c9 (TCGA-B6-A0WX.EE5BB205-D59B-4FEF-8D8F-D5720EDEB075.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).